Gene-level copy-number profile of tumor specimen TCGA-AO-A1KS-01A from TCGA case TCGA-AO-A1KS, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 69.1 years (25,230 days).
Specimen TCGA-AO-A1KS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.4f393818-bf59-495d-85cf-6ddf1571e717.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AO-A1KS-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ac7b2b09-dd4e-4d2c-a944-2105121885d8

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 17; copy number 2: 14,394; copy number 3: 11,769; copy number 4: 27,916; copy number 5: 3,213; copy number 6: 656; copy number 7: 293; copy number 8: 281; copy number 9: 1,081; copy number 11: 39; copy number 21: 4; copy number 22: 14; copy number 23: 18; copy number 24: 2; copy number 27: 40; copy number 29: 36; copy number 30: 4; copy number 33: 6; copy number 35: 3; copy number 39: 27.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AO-A1KS-01A-11D-A13J-01): tumor purity 0.64, ploidy 3.46, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,274 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:114,314,500–115,147,288, 1 gene, copy number 9 (within-gene range 7–9): ZBTB20.
- chr3:114,743,445–117,139,389, 18 genes, copy number 9 (within-gene range 4–9): MIR4796, ZBTB20-AS3, YBX1P3, ZBTB20-AS4, AC026341.1, EIF4E2P2, AC026341.2, AC026341.3, GAP43, AC092468.1, LSAMP, RN7SL815P, LSAMP-AS1, LINC00903, RN7SL582P, BZW1P2, TUSC7, AC108713.1.
- chr8:78,148,101–145,066,685, 1,062 genes, copy number 9 (broad region; genes not listed).
- chr13:27,162,855–27,744,237, 18 genes, copy number 23: USP12-AS1, USP12-AS2, LINC02340, LINC00412, RPL21, SNORD102, SNORA27, RASL11A, RNU6-70P, LINC01079, RNY1P1, GTF3A, MTIF3, RNU6-63P, LNX2, POLR1D, AL136439.1, NPM1P4.
- chr13:30,684,029–31,332,276, 14 genes, copy number 22 (within-gene range 7–22): Metazoa_SRP, ALOX5AP, LINC00398, LINC00545, TEX26-AS1, MEDAG, TEX26, AL353680.1, LINC01066, AL158065.1, WDR95P, HSPH1, B3GLCT, ANKRD26P4.
- chr13:33,800,138–37,874,444, 54 genes, copy number 11–27: AL139081.2, RFC3, RNU5A-4P, AL161891.1, AL160394.2, VDAC1P12, AL160394.1, AL356321.1, LINC02343, LINC00457, AL161716.1, GAMTP2, Metazoa_SRP, AL138690.1, NBEA, SCAND3P1, PHBP13, MAB21L1, AL390071.1, LINC00445, DCLK1, SOHLH2, CCDC169-SOHLH2, CCDC169, RNU6-71P, SPART, SPART-AS1, CCNA1, H2ACP1, SERTM1, GAPDHP34, TCEAL4P1, ARL2BPP3, NDE1P2, RFXAP, SMAD9, SMAD9-IT1, LAMTOR3P1, RPL29P28, EIF4A1P5, ALG5, EXOSC8, SUPT20H, CSNK1A1L, AL356274.1, AL356274.2, RN7SKP1, RPS12P24, LINC01048, LINC00547, POSTN, TRPC4, RNA5SP26, AL356495.1.
- chr13:50,519,364–52,739,820, 58 genes, copy number 11–39 (within-gene range 8–39): DLEU7, RNA5SP28, RNASEH2B-AS1, RNASEH2B, GUCY1B2, RNA5SP29, C13orf42, RPL5P31, AL157817.1, PRELID3BP2, FAM124A, SERPINE3, MIR5693, INTS6, INTS6-AS1, RPS4XP16, RN7SL320P, SNRPGP11, MIR4703, RNU6-65P, WDFY2, RNY1P6, RN7SL413P, ATP5PBP1, AL162377.3, DHRS12, AL162377.1, TMEM272, CCDC70, CTAGE3P, AL162377.2, ATP7B, FABP5P2, ALG11, UTP14C, NEK5, AL139082.1, NEK3, MRPS31P5, AL158066.1, THSD1P1, AL158066.2, TPTE2P2, LINC02333, THSD1, RNY4P24, VPS36, AL359513.1, CKAP2, LINC00345, AL137058.1, AL137058.3, AL137058.2, MRPS31P4, HNRNPA1L2, SUGT1-DT, SUGT1, CNMD.
- chr20:46,364,551–46,459,276, 3 genes, copy number 35 (within-gene range 3–35): AL133227.1, ELMO2, ZNF663P.
- chr20:47,826,969–47,904,423, 4 genes, copy number 21: RNU7-173P, SRMP1, RNA5SP486, RNU7-92P.
- chr20:49,794,811–50,882,676, 36 genes, copy number 29 (within-gene range 3–29): RNU6-919P, SLC9A8, AL162615.1, SPATA2, Y_RNA, Metazoa_SRP, RNF114, KRT18P4, RNU6-147P, SNAI1, TRERNA1, UBE2V1, PEDS1-UBE2V1, PEDS1, LINC01275, AL161937.1, LINC01273, CEBPB-AS1, CEBPB, PELATON, LINC01270, LINC01271, RN7SL636P, COX6CP2, PTPN1, RN7SL672P, Y_RNA, AL133230.1, MIR645, RIPOR3, MIR1302-5, RPL36P2, RIPOR3-AS1, PARD6B, BCAS4, TMSB4XP6.
- chr20:53,544,615–53,741,797, 6 genes, copy number 33: Y_RNA, AL157838.1, ZNF217, AC005808.1, RNU7-14P, AC005914.1.

Autosomal genes at a single copy (total copy number 1): 17. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
